Somatic mutation profile of cancer-model specimen HCM-BROD-0578-C15-85M (3D Organoid, passage 3; aliquot HCM-BROD-0578-C15-85M-01D-A83U-36), derived from the metastatic tumor of HCMI case HCM-BROD-0578-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; AJCC pathologic stage: Stage IV; Tumor grade: GX; Age at diagnosis: 46.7 years (17,054 days).
Specimen HCM-BROD-0578-C15-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 3.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 360ef53b-30d7-4dec-b1b9-551d6fb6487d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0578-C15-10A (Blood Derived Normal), aliquot HCM-BROD-0578-C15-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/24003eaa-7dfe-4d9a-a76b-0480247baafa

The open-access MAF lists 41 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 9, Intron 3, Nonsense Mutation 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.9670G>T p.D3224Y | Missense Mutation (SNP) | VAF 186/406 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52506062; called by muse, mutect2, varscan2
- CDH1 | c.763C>T p.Q255* | Nonsense Mutation (SNP) | VAF 457/458 reads (100%) | catalogued as COSV55727283; called by muse, mutect2, varscan2
- DHX35 | c.1253C>T p.T418M | Missense Mutation (SNP) | VAF 136/267 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs376209770; called by muse, mutect2, varscan2
- FBXO42 | c.1669C>T p.R557C | Missense Mutation (SNP) | VAF 631/631 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs565632708; called by muse, mutect2, varscan2
- FSTL5 | c.1243G>A p.A415T | Missense Mutation (SNP) | VAF 155/368 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs756146269, COSV60182341; called by muse, mutect2, varscan2
- HCRTR1 | c.734G>A p.R245H | Missense Mutation (SNP) | VAF 128/281 reads (46%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.847); catalogued as rs200636229; called by muse, mutect2, varscan2
- HDAC9 | c.2404G>A p.A802T | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1328935755, COSV101287580; called by muse, mutect2, varscan2
- OR6T1 | c.526C>A p.H176N | Missense Mutation (SNP) | VAF 274/557 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1371737888; called by muse, mutect2, varscan2
- RIMS1 | c.4142C>A p.P1381H | Missense Mutation (SNP) | VAF 95/187 reads (51%) | SIFT tolerated (0.4); PolyPhen probably damaging (0.996); catalogued as COSV53453696, COSV53457688; called by muse, mutect2, varscan2
- THADA | c.5382G>C p.Q1794H | Missense Mutation (SNP) | VAF 362/779 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs756831818; called by muse, mutect2, varscan2
- ARMC8 | c.1269G>T p.Q423H (on ENST00000469044 / NM_001363941.2; = p.Q409H on NM_015396.6) | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2
- BAIAP2L2 | c.630G>C p.Q210H | Missense Mutation (SNP) | VAF 268/588 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.553); called by muse, mutect2, varscan2
- C7 | c.305T>C p.V102A | Missense Mutation (SNP) | VAF 126/299 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CCNB1 | c.802G>A p.D268N | Missense Mutation (SNP) | VAF 198/404 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CTNNA2 | c.610G>C p.D204H | Missense Mutation (SNP) | VAF 198/401 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRM8 | c.925G>C p.D309H | Missense Mutation (SNP) | VAF 131/349 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HPGD | c.683G>T p.G228V | Missense Mutation (SNP) | VAF 106/221 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRP6 | c.2911G>C p.D971H | Missense Mutation (SNP) | VAF 230/466 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- LTK | c.1117G>T p.V373L | Missense Mutation (SNP) | VAF 183/407 reads (45%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- MYO16 | c.3818G>A p.W1273* | Nonsense Mutation (SNP) | VAF 390/1162 reads (34%) | called by muse, mutect2, varscan2
- PRRT4 | c.2401G>A p.V801I | Missense Mutation (SNP) | VAF 494/1011 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- PUM3 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 119/119 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF38 | c.1133C>T p.P378L | Missense Mutation (SNP) | VAF 147/315 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.367); called by muse, mutect2, varscan2
- SMPDL3B | c.451T>C p.Y151H | Missense Mutation (SNP) | VAF 17/340 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- TERB2 | c.533C>T p.S178L | Missense Mutation (SNP) | VAF 16/272 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2
- TTC30A | c.686T>A p.M229K | Missense Mutation (SNP) | VAF 257/533 reads (48%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- TYMP | c.1175T>C p.V392A | Missense Mutation (SNP) | VAF 46/944 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); called by muse, mutect2
- UTP20 | c.1251G>A p.Q417= | Splice Region (SNP) | VAF 88/223 reads (39%) | called by muse, mutect2, varscan2
- ZNF644 | c.2599G>C p.G867R | Missense Mutation (SNP) | VAF 208/435 reads (48%) | SIFT tolerated (0.13); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CAMK2A | c.1392C>T p.I464= (on ENST00000348628 / NM_171825.2; = p.I475= on NM_015981.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 282/598 reads (47%) | catalogued as rs912865720, COSV62245003; called by muse, mutect2
- CGAS | c.237C>T p.A79= | Silent (SNP) | VAF 481/914 reads (53%) | called by muse, mutect2, varscan2
- CYP27C1 | c.408C>T p.N136= | Silent (SNP) | VAF 17/317 reads (5%) | called by muse, mutect2
- ECEL1 | c.1854C>T p.Y618= | Silent (SNP) | VAF 237/523 reads (45%) | catalogued as rs372170199; called by muse, mutect2, varscan2
- HTRA4 | c.210C>T p.R70= | Silent (SNP) | VAF 452/951 reads (48%) | called by muse, mutect2, varscan2
- JMJD1C | c.4044C>T p.A1348= | Silent (SNP) | VAF 194/441 reads (44%) | catalogued as rs762369149; ClinVar: likely benign; called by muse, mutect2, varscan2
- LIPF | c.390T>C p.Y130= | Silent (SNP) | VAF 159/344 reads (46%) | called by muse, varscan2
- NFASC | c.3051G>A p.T1017= | Silent (SNP) | VAF 204/517 reads (39%) | catalogued as rs765463710; called by muse, mutect2, varscan2
- PHF2 | c.1269G>A p.P423= | Silent (SNP) | VAF 215/621 reads (35%) | catalogued as COSV63683799; called by muse, mutect2, varscan2
- CSNK2A1 | c.213+1497A>G | Intron (SNP) | VAF 346/557 reads (62%) | catalogued as rs192907725; called by muse, mutect2, varscan2
- EYS | c.1766+13C>A | Intron (SNP) | VAF 10/216 reads (5%) | called by muse, mutect2
- MTURN | c.163-260T>G | Intron (SNP) | VAF 206/429 reads (48%) | called by muse, mutect2, varscan2
